Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A51N, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A51N-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

- (A) RIGHT CHEST WALL, SKIN ELLIPSE:
SKIN AND SUBCUTIS WITH DERMAL SCAR AND MELANOMA INVOLVING SUBCUTANEOUS ADIPOSE TISSUE (5.0 X 4.0 X 4.0 MM, PER GROSS DESCRIPTION).
TUMOR BORDERS: PUSHING.
Margins of resection have been evaluated and are free of melanoma.
- (B) RIGHT ADRENAL, ADRENALECTOMY:
MELANOMA, METASTATIC TO ADRENAL GLAND.
TUMOR SIZE: 21.0 X 20.0 X 18.0 MM (PER GROSS DESCRIPTION.)
- (C) LEFT SUPERFICIAL FEMORAL LYMPH NODES, SKIN ELLIPSE AND LYMPHADENECTOMY:
SKIN AND SUBCUTIS WITH MELANOMA INVOLVING SUBCUTANEOUS FIBROCONNECTIVE TISSUE.
TUMOR SIZE: 63.0 X 61.0 X 40.0 MM (AS PER GROSS DESCRIPTION; A COMPLETELY REPLACED BY TUMOR LYMPH NODE CANNOT BE RULED OUT.)
TUMOR BORDERS: PUSHING.
Inked deep margin of resection appears free of melanoma.
- Four lymph nodes, negative for melanoma (0/4.)
- (D) LEFT ILIAC AND OBTURATOR LYMPH NODES, LYMPHADENECTOMY:
Seven lymph nodes, negative for melanoma (0/7).

1CD-0-3

Melanoma, NOS 8720/3

Sites lymph node, femoral 077.4

11/6/12

GROSS DESCRIPTION

- (A) RESECTION OF METASTATIC MELANOMA - RIGHT CHEST WALL, SHORT SUPERIOR, LONG POSTERIOR - An ellipse of lightly pigmented skin with attached subcutaneous tissue, 5.1 cm posterior to anterior, 2.8 cm superior to inferior x 1.9 cm of superficial to deep. There is a centrally located flesh-colored scar, 0.9 x 0.8 cm, 1.0 cm from the closest superior tissue edge. Subjacent to the scar, there is a faint, off-white nodular lesion, 0.5 x 0.5 x 0.4 cm, 0.6 cm from the closest superior tissue edge, 1.0 cm from the closest deep tissue edge, and 2.1 cm from the closest inferior tissue edge.
INK CODE: Blue - superior; orange - inferior.
SECTION CODE: A1, posterior tip; A2, anterior tip; A3-A8, skin with scar and subjacent off-white nodule in toto; A9, closest perpendicular inferior tissue edge, representative sections.
- (B) RIGHT ADRENAL GLAND WITH TUMOR - Adrenal gland, 5.5 x 2.0 x 2.2 cm.
There is an off-white well circumscribed fibrous nodule, 2.1 x 2.0 x 1.8 cm located within the adrenal gland and encompassed by a rim of fibroadipose tissue. The remaining adrenal gland is grossly unremarkable.
SECTION CODE: B1-B4, adrenal gland with tumor; B5, uninvolved adrenal gland representative sections.
- (C) LEFT SUPERFICIAL FEMORAL LYMPH NODES FOR MELANOMA TUMOR BANK - A tan-white skin ellipse (27.0 x 6.8 cm) with underlying subcutaneous adipose tissue (30.0 x 12.0 x 4.0 cm). In the center of the specimen, there is a firm brown possible lymph node (6.3 x 6.1 x 4.0 cm), whose capsule abuts the deep surface and is 1.0 cm from the skin surface. This mass is well encapsulated. Within the additional soft tissue, four possible lymph nodes (0.9 - 1.5 cm in greatest dimension) are identified. Portions are submitted for tissue bank. Representative sections of the largest possible node are submitted. The smaller lymph nodes are entirely submitted.
INK CODE: Blue - deep surface.
SECTION CODE: C1-C3, representative sections of largest central node; C4, two nodes; C5, one node; C6, one trisected node.
- (D) LEFT ILIAC AND OBTURATOR NODES - Fibroadipose tissue, 8.2 x 7.9 x 1.8 cm yielding seven possible lymph nodes ranging in greatest dimension from 0.5 to 5.8 cm.
SECTION CODE: D1-D3, one lymph node serially sectioned; D4, D5, one lymph node serially sectioned; D6, one lymph node serially sectioned; D7, one lymph node bisected; D8, three possible lymph nodes.

CLINICAL HISTORY

Melanoma.

[page 2 of 2]
SNOMED CODES

T-02424, T-C4000, T-B3000, M-78060, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Primary To not Site Discrepancy		☒

Source: NCI Genomic Data Commons file 0853388d-d981-4ca6-827d-d2ac210d8455 (TCGA-D3-A51N.A0357EE6-DEF6-47B5-A106-CEBB387D55C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).